Surgical pathology report (de-identified scan), TCGA case TCGA-85-A512, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-A512-01A (Primary Tumor).

ICD-0-3

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

carcinoma, squamous cell, NOS 8070/3
Site: lung, @upper lobe c34.3
pw
11/8/12

Formatted Path Reports: LUNG TISSUE CHECKLIST

Specimen type: Left pneumonectomy

Tumor site: Lung

Tumor size: 3 x 3 x 3 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Not specified

Other tumor nodules: Not specified

Lymph nodes: 8/12 positive for metastasis (Intrathoracical 8/12)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Left- upper

Source: NCI Genomic Data Commons file ddf6826f-6f58-492d-bf79-b7f0451a40a4 (TCGA-85-A512.A49AF0B2-6C19-47D5-BD75-A6CB7F7057B9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).